MMRF case MMRF_2224 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/63c48188-062c-411d-91c4-7c42764c6ba3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.5 years (20,649 days); ISS stage: III; Days to last known disease status: 895 days (2.5 years); Days to last follow up: 895 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 400 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 401 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 45 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 242 days; Days to treatment end: 242 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 477 days (1.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.037 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 235 mg/dL; Immunoglobulin G 3.17 g/L; Immunoglobulin A 0.073 g/L; Immunoglobulin M 0.053 g/L; Beta 2 Microglobulin 5.9 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 7.78 ×10⁹/L; Absolute Neutrophil 5.72 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 112 µmol/L; Calcium 2.73 mmol/L; Total Protein 7.1 g/dL; Glucose 5.72 mmol/L; C-Reactive Protein 0.186 mg/dL.
- Day 75 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.634 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 4.06 g/L; Immunoglobulin A 0.067 g/L; Immunoglobulin M 0.414 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 10.2 mmol/L; Leukocytes 11.7 ×10⁹/L; Absolute Neutrophil 8.51 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 75.1 µmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 5.67 mmol/L.
- Day 172 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.42 mg/dL; Immunoglobulin G 4.93 g/L; Immunoglobulin A 0.631 g/L; Immunoglobulin M 0.323 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 10.1 mmol/L; Leukocytes 4.41 ×10⁹/L; Absolute Neutrophil 2.46 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 92.8 µmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 6 mmol/L.
- Day 270 (ECOG 1): Lactate Dehydrogenase 3.85 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.48 ×10⁹/L; Absolute Neutrophil 1.56 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 73.4 µmol/L; Calcium 2.4 mmol/L; Total Protein 5.9 g/dL; Glucose 5.45 mmol/L.
- Day 362 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.687 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.552 mg/dL; Immunoglobulin G 4.77 g/L; Immunoglobulin A 0.342 g/L; Immunoglobulin M 0.642 g/L; Beta 2 Microglobulin 2.34 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 4.12 ×10⁹/L; Absolute Neutrophil 2.11 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 73.4 µmol/L; Calcium 2.4 mmol/L; Total Protein 5.9 g/dL; Glucose 5.39 mmol/L.
- Day 439 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.881 mg/dL; Immunoglobulin G 4.58 g/L; Immunoglobulin A 0.409 g/L; Immunoglobulin M 0.414 g/L; Beta 2 Microglobulin 2.87 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 9.55 mmol/L; Leukocytes 5.13 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 76 µmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 6.4 g/dL; Glucose 6.11 mmol/L.
- Day 533 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.779 mg/dL; Immunoglobulin G 4.73 g/L; Immunoglobulin A 0.411 g/L; Immunoglobulin M 0.602 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 9.92 mmol/L; Leukocytes 4.82 ×10⁹/L; Absolute Neutrophil 2.05 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 81.3 µmol/L; Calcium 2.38 mmol/L; Total Protein 5.9 g/dL; Glucose 5.17 mmol/L.
- Day 613 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Immunoglobulin G 8.16 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 1.85 g/L; Lactate Dehydrogenase 4.42 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 4.43 ×10⁹/L; Absolute Neutrophil 1.14 ×10⁹/L; Platelets 36.6 ×10⁹/L; Creatinine 86.6 µmol/L; Calcium 2.28 mmol/L; Total Protein 6.4 g/dL; Glucose 5.34 mmol/L.
- Day 701 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 5.76 g/L; Immunoglobulin A 0.645 g/L; Immunoglobulin M 0.496 g/L; Lactate Dehydrogenase 4.15 µkat/L; Hemoglobin 9.86 mmol/L; Leukocytes 3.66 ×10⁹/L; Absolute Neutrophil 1.25 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 93.7 µmol/L; Calcium 2.4 mmol/L; Total Protein 6.6 g/dL; Glucose 5.78 mmol/L.
- Day 820 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 6.38 g/L; Immunoglobulin A 0.918 g/L; Immunoglobulin M 0.452 g/L; Lactate Dehydrogenase 4.18 µkat/L; Hemoglobin 10.5 mmol/L; Leukocytes 5.88 ×10⁹/L; Absolute Neutrophil 3.14 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 92.8 µmol/L; Calcium 2.38 mmol/L; Total Protein 6.2 g/dL; Glucose 5.89 mmol/L.
- Day 895 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 5.48 g/L; Immunoglobulin A 0.586 g/L; Immunoglobulin M 0.346 g/L; Lactate Dehydrogenase 4.05 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 4.05 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 86.6 µmol/L; Calcium 2.38 mmol/L; Total Protein 6.5 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day -3: Weight: 79 kg; Height: 184 cm.

Biospecimens (2 samples)
- Sample MMRF_2224_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2224_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
